Somatic mutation profile of tumor specimen TCGA-69-8255-01A (aliquot TCGA-69-8255-01A-11D-2284-08) from TCGA case TCGA-69-8255, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Solid carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 72.0 years (26,289 days).
Specimen TCGA-69-8255-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 960c38ee-03c4-4b33-8085-974c58cf6d83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-69-8255-10A (Blood Derived Normal), aliquot TCGA-69-8255-10A-01D-2284-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2025176-89e8-4afd-8e08-3b89c336e0c2

The open-access MAF lists 317 somatic variants for this specimen: 245 protein-altering or splice-affecting, 63 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 199, Silent 63, Nonsense Mutation 22, Frame Shift Del 11, Splice Region 5, Frame Shift Ins 4, Splice Site 4, RNA 4, Intron 3, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NOTCH1 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53027071; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 28/69 reads (41%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.754T>G p.L252V | Missense Mutation (SNP) | VAF 23/322 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.771); catalogued as COSV100735664; called by muse, mutect2
- ABCG4 | c.680C>A p.P227H | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100266493; called by muse, mutect2, varscan2
- ACSS1 | c.1247-2A>G p.X416_splice | Splice Site (SNP) | VAF 13/55 reads (24%) | catalogued as COSV100053349; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4658G>A p.C1553Y | Missense Mutation (SNP) | VAF 38/286 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV99716784; called by muse, mutect2, varscan2
- AK9 | c.5672T>C p.I1891T | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as COSV101413927; called by muse, mutect2, varscan2
- ALPP | c.813C>A p.N271K | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.768); catalogued as rs1235031507, COSV101235073; called by muse, mutect2
- ANKS1B | c.34C>G p.R12G | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100242639, COSV100245378, COSV100247839; called by muse, mutect2, varscan2
- AQP12A | c.225G>C p.L75F | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV100538611; called by muse, mutect2, varscan2
- ARHGAP33 | c.2453T>G p.L818R | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99137537; called by muse, mutect2
- ATP2B3 | c.1415C>A p.S472Y | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99682860; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1885A>T p.N629Y | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100376803; called by muse, mutect2, varscan2
- BARD1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV53617881, COSV99038470; called by muse, mutect2, varscan2
- BCL11A | c.1231G>T p.A411S (on ENST00000335712 / NM_001365609.1; = p.A445S on NM_018014.4) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.233); catalogued as COSV100184710, COSV59626834; called by muse, mutect2, varscan2
- BMP3 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 21/41 reads (51%) | catalogued as COSV99261349, COSV99262004; called by muse, mutect2, varscan2
- C7 | c.1348G>T p.D450Y | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); catalogued as COSV100495357, COSV57481506; called by muse, mutect2, varscan2
- CACHD1 | c.2027G>A p.R676H | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs767641308, COSV51562547; called by muse, mutect2, varscan2
- CACNA1S | c.1230C>T p.F410= | Splice Region (SNP) | VAF 7/64 reads (11%) | catalogued as COSV100754630; called by muse, mutect2
- CACNG2 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100268472, COSV104411030; called by muse, mutect2, varscan2
- CADPS | c.3206G>A p.W1069* | Nonsense Mutation (SNP) | VAF 5/56 reads (9%) | catalogued as COSV99335733; called by muse, mutect2
- CCNI2 | c.573C>G p.Y191* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | catalogued as COSV101107740; called by muse, mutect2, varscan2
- CCT7 | c.1458C>A p.D486E | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99240508; called by muse, mutect2, varscan2
- CD1B | c.373G>T p.G125* | Nonsense Mutation (SNP) | VAF 68/273 reads (25%) | catalogued as COSV100939127; called by muse, mutect2, varscan2
- CDC25A | c.994A>G p.N332D | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV100207301; called by muse, mutect2, varscan2
- CDH7 | c.1613-1G>C p.X538_splice | Splice Site (SNP) | VAF 21/81 reads (26%) | catalogued as COSV100541349; called by muse, mutect2, varscan2
- CENPE | c.7976G>T p.R2659L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV99476913; called by muse, mutect2, varscan2
- CEP57 | c.1435C>T p.Q479* | Nonsense Mutation (SNP) | VAF 23/87 reads (26%) | catalogued as COSV100334563; called by muse, mutect2, varscan2
- CEP68 | c.1298T>G p.M433R | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.043); catalogued as rs746213881, COSV99560553; called by muse, mutect2, varscan2
- CHAF1A | c.1324A>G p.K442E | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100010797; called by muse, mutect2, varscan2
- CHD7 | c.6649G>T p.E2217* | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | catalogued as COSV101417943, COSV101417972; called by muse, mutect2, varscan2
- CIT | c.4001C>T p.A1334V | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.34); catalogued as COSV99948301; called by muse, mutect2, varscan2
- CKAP4 | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100952388, COSV100952418; called by muse, mutect2, varscan2
- CNST | c.814C>G p.Q272E | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV100829790; called by muse, mutect2, varscan2
- CNTN1 | c.1508-1G>T p.X503_splice | Splice Site (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100750922; called by muse, mutect2, varscan2
- CORO6 | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1447995407, COSV61471502; called by muse, mutect2, varscan2
- CPLANE1 | c.*4668G>A | Splice Region (SNP) | VAF 13/47 reads (28%) | catalogued as COSV99949532; called by muse, mutect2, varscan2
- CR1 | c.3853G>T p.V1285F | Missense Mutation (SNP) | VAF 68/238 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV100887374; called by muse, mutect2, varscan2
- CSMD3 | c.7291G>A p.G2431S (on ENST00000297405 / NM_001363185.1; = p.G2327S on NM_052900.3) | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99823771; called by muse, mutect2, varscan2
- CTNND2 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV100471355; called by muse, mutect2, varscan2
- CUBN | c.2639C>A p.S880Y | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100912027; called by muse, mutect2, varscan2
- CYBRD1 | c.348G>C p.M116I | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV100361161; called by muse, mutect2, varscan2
- DCLK1 | c.2096G>T p.R699L (on ENST00000360631 / NM_001330072.2; = p.E724* on NM_004734.5) | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.137); catalogued as COSV55199051, COSV99708982; called by muse, mutect2, varscan2
- DNAI4 | c.1475C>A p.A492D | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV100925258; called by muse, mutect2, varscan2
- DPP10 | c.504G>T p.W168C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as COSV100058212; called by muse, mutect2, varscan2
- DRC7 | c.1382G>T p.R461L | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100395351; called by muse, mutect2, varscan2
- ECI1 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as rs758776830, COSV100066451; called by muse, mutect2, varscan2
- EPHA8 | c.1810C>G p.L604V | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV99384162; called by muse, mutect2, varscan2
- FAM216B | c.35G>T p.W12L | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.67); PolyPhen benign (0.025); catalogued as COSV100573033; called by muse, mutect2, varscan2
- FAM216B | c.36G>T p.W12C | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100573035; called by muse, mutect2, varscan2
- FAM47A | c.875A>T p.E292V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.607); catalogued as COSV100649710; called by mutect2, varscan2
- FAM47A | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100649711; called by muse, mutect2, varscan2
- FANCD2 | c.3770C>G p.S1257W | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99810271; called by muse, mutect2
- FAT1 | c.5786T>A p.M1929K | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV101498931; called by muse, varscan2
- FDX1 | c.491C>G p.T164S | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV99501743; called by muse, mutect2, varscan2
- FGD6 | c.1483G>A p.V495I | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100676345; called by muse, mutect2
- FLG | c.2671A>G p.S891G | Missense Mutation (SNP) | VAF 93/615 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100910462, COSV64239905; called by muse, mutect2, varscan2
- FOSL2 | c.431G>C p.R144P | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99268196, COSV99268638; called by mutect2, varscan2
- FOXM1 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs748271869, COSV100700793; called by muse, mutect2, varscan2
- GABRG2 | c.1355A>G p.K452R (on ENST00000361925 / NM_001375343.1; = p.K412R on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); catalogued as COSV100729504; called by muse, varscan2
- GATAD1 | c.604G>T p.A202S | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs564747350, COSV99843623; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GCNA | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV101032371; called by muse, varscan2
- GDAP1 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99619299; called by muse, mutect2, varscan2
- GPLD1 | c.144C>A p.N48K | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV100014965; called by muse, mutect2, varscan2
- GPN2 | c.178G>T p.V60L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV100658685; called by muse, mutect2, varscan2
- GRIK2 | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100022813, COSV59719917; called by muse, mutect2, varscan2
- GRIK2 | c.2699G>T p.R900M | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV100022809, COSV100022818; called by muse, mutect2, varscan2
- GRXCR1 | c.592del p.L198Sfs*20 | Frame Shift Del (DEL) | VAF 288/674 reads (43%) | catalogued as COSV67670672; called by mutect2, pindel, varscan2
- GTF2E1 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1241939211, COSV52206169, COSV52206631; called by muse, mutect2, varscan2
- H2AC8 | c.186G>C p.E62D | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV55126218, COSV99773021; called by muse, mutect2, varscan2
- H3C13 | c.237dup p.K80* | Frame Shift Ins (INS) | VAF 20/79 reads (25%) | catalogued as rs1553754909; called by mutect2, pindel, varscan2
- HCN1 | c.1042G>T p.A348S | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.357); catalogued as COSV100298381, COSV57492101, COSV57537055; called by muse, mutect2, varscan2
- HERC2 | c.9298C>A p.R3100S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99870707; called by muse, mutect2, varscan2
- HFE | c.722A>T p.K241M | Missense Mutation (SNP) | VAF 68/121 reads (56%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV100352497; called by muse, mutect2, varscan2
- HFM1 | c.1079A>T p.N360I | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV99645287; called by muse, mutect2, varscan2
- HOATZ | c.175G>C p.D59H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as rs1052632049, COSV100239331; called by muse, mutect2, varscan2
- HPS4 | c.1335C>G p.D445E | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.442); catalogued as rs1368223008, COSV100403979; called by muse, mutect2, varscan2
- HTR1A | c.589A>C p.I197L | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV100108885; called by muse, mutect2, varscan2
- HTT | c.4750G>C p.V1584L | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100750372; called by muse, mutect2, varscan2
- IL1RAPL1 | c.2060G>T p.R687M | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV100145002; called by muse, mutect2, varscan2
- INO80 | c.68A>T p.Q23L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100731525; called by muse, mutect2, varscan2
- IRF2BP2 | c.1562G>C p.C521S | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100784240; called by muse, mutect2, varscan2
- IRX6 | c.836G>T p.G279V | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99306184; called by muse, varscan2
- ITGA6 | c.1945G>T p.D649Y (on ENST00000442250; = p.D610Y on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.161); catalogued as COSV99904994; called by muse, mutect2, varscan2
- KAT14 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | catalogued as COSV100890026; called by muse, mutect2
- KIAA1109 | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | catalogued as COSV99145685; called by muse, mutect2, varscan2
- KIF20A | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1156620704, COSV99136572; called by muse, mutect2, varscan2
- KLHL10 | c.1468G>A p.G490R | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV99509409; called by muse, mutect2, varscan2
- KLHL5 | c.1750C>G p.Q584E | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV54678946; called by muse, mutect2
- KRTAP10-9 | c.185G>C p.C62S | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV100551792; called by muse, mutect2
- KRTAP5-10 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 80/257 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.031); catalogued as COSV100924122; called by muse, mutect2, varscan2
- LGR4 | c.2401T>C p.Y801H | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100156377; called by muse, mutect2, varscan2
- LHCGR | c.167T>G p.L56R | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54303384, COSV99683127; called by muse, mutect2, varscan2
- LRFN2 | c.11T>C p.L4P | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV100599085; called by muse, mutect2
- MACROD2 | c.1357A>T p.K453* (on ENST00000642719; = p.K425* on NM_080676.6 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99426640; called by muse, mutect2, varscan2
- MBD5 | c.2585C>G p.T862R | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV101289923; called by muse, mutect2
- MCM10 | c.910G>C p.V304L (on ENST00000484800 / NM_182751.3; = p.V303L on NM_018518.5) | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV101097915; called by muse, mutect2, varscan2
- MDM2 | c.458C>A p.P153H | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV99254280; called by muse, mutect2, varscan2
- MEGF10 | c.803G>T p.C268F | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99174696; called by muse, mutect2, varscan2
- MFSD1 | c.587A>T p.Y196F | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV99963593; called by muse, mutect2, varscan2
- MICAL2 | c.5750A>T p.Q1917L | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV99811400; called by muse, mutect2, varscan2
- MRPL54 | c.164C>G p.A55G | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.118); catalogued as rs867258969, COSV100349547; called by muse, mutect2, varscan2
- MSH2 | c.2128G>C p.A710P | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1558519878, COSV99253117; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC17 | c.9829A>T p.S3277C | Missense Mutation (SNP) | VAF 190/780 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100071485; called by muse, mutect2, varscan2
- MUC5AC | c.14754G>T p.Q4918H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100611307; called by muse, mutect2, varscan2
- MYBPC1 | c.2216G>A p.R739H (on ENST00000550270 / NM_206820.2; = p.R764H on NM_002465.4) | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765766176; called by muse, mutect2
- MYH15 | c.4915C>T p.L1639F | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV99842175; called by muse, mutect2, varscan2
- MYH2 | c.2307C>G p.V769= | Splice Region (SNP) | VAF 31/99 reads (31%) | catalogued as COSV55438931, COSV99819202; called by muse, mutect2, varscan2
- MYO7B | c.4117G>A p.V1373I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.97); PolyPhen benign (0.069); catalogued as rs761760742, COSV67344401; called by muse, mutect2, varscan2
- MYOM2 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as rs779788503, COSV50705721; called by muse, mutect2, varscan2
- NAE1 | c.1058A>G p.D353G | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs772975515, COSV99322930; called by muse, mutect2, varscan2
- NCKAP5 | c.1667C>T p.T556M | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs201814216, COSV58433575; called by muse, mutect2, varscan2
- NCOA6 | c.2023C>T p.Q675* | Nonsense Mutation (SNP) | VAF 17/82 reads (21%) | catalogued as COSV100749898; called by muse, mutect2, varscan2
- NDUFS7 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs776450572, COSV99282594; called by muse, mutect2, varscan2
- NFKB1 | c.1310C>T p.T437I (on ENST00000394820 / NM_001382627.1; = p.T438I on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.069); catalogued as COSV99896622; called by muse, mutect2, varscan2
- NFYC | c.167A>T p.E56V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100438221; called by muse, mutect2, varscan2
- NNT | c.1522del p.A508Lfs*12 | Frame Shift Del (DEL) | VAF 62/268 reads (23%) | catalogued as COSV52922576; called by mutect2, pindel*, varscan2
- NPAP1 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.105); catalogued as COSV100274744; called by muse, mutect2, varscan2
- NR3C2 | c.1091C>T p.T364M | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as rs776434075, COSV100678638; called by muse, mutect2, varscan2
- NRDC | c.2101A>G p.I701V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755683229, COSV100703054; called by muse, mutect2, varscan2
- NRP2 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.04); catalogued as COSV99783423; called by muse, mutect2, varscan2
- NRXN1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs200781129, COSV68032996, COSV99065640; called by muse, mutect2, varscan2
- NTNG1 | c.463G>T p.G155W | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763366087, COSV53988249; called by muse, mutect2, varscan2
- NUDC | c.988T>G p.F330V | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV100264364; called by muse, mutect2, varscan2
- NUF2 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99616067; called by muse, mutect2, varscan2
- NVL | c.122G>A p.R41K | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99893632; called by muse, mutect2, varscan2
- OPHN1 | c.1852A>G p.T618A | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100830199; called by muse, mutect2, varscan2
- OPN3 | c.416G>C p.R139P | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100086987, COSV59364065; called by muse, mutect2, varscan2
- OR2T2 | c.328G>T p.G110* | Nonsense Mutation (SNP) | VAF 53/344 reads (15%) | catalogued as COSV100737548, COSV61618333; called by muse, mutect2, varscan2
- OR4K1 | c.394T>A p.Y132N | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99578612; called by muse, mutect2
- OR4X1 | c.192A>T p.L64F | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as rs905426108, COSV100186535; called by muse, mutect2
- OR5V1 | c.632T>G p.F211C | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.961); catalogued as COSV101011097; called by muse, mutect2, varscan2
- OR6K2 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV100656682; called by muse, mutect2, varscan2
- P2RY2 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1215781979, COSV100232615; called by muse, mutect2, varscan2
- PAIP1 | c.550G>C p.A184P | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100166484; called by muse, mutect2, varscan2
- PAPPA2 | c.1058T>A p.L353* | Nonsense Mutation (SNP) | VAF 26/105 reads (25%) | catalogued as COSV100866518; called by muse, mutect2, varscan2
- PAPPA2 | c.2001G>T p.M667I | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as COSV100866519; called by muse, mutect2, varscan2
- PAPPA2 | c.4585C>A p.P1529T | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV100867511; called by muse, mutect2, varscan2
- PCMT1 | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100953379; called by muse, mutect2, varscan2
- PLXNB2 | c.3211G>T p.V1071L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs1213754705, COSV100833841; called by muse, mutect2, varscan2
- PLXND1 | c.4643G>T p.R1548L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100138991, COSV100139352; called by muse, mutect2, varscan2
- PNLIPRP3 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0.03); catalogued as COSV100982328; called by muse, mutect2, varscan2
- POLQ | c.998C>A p.T333K | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs189092204, COSV99951545; called by muse, mutect2, varscan2
- PRC1 | c.558A>C p.E186D | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.075); catalogued as COSV100727025; called by muse, mutect2, varscan2
- PRG4 | c.574A>G p.R192G | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); catalogued as COSV100825599; called by muse, mutect2, varscan2
- PRKDC | c.9544A>G p.I3182V | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as rs1296572030, COSV100038266; called by muse, mutect2
- PRKRA | c.678C>G p.I226M | Missense Mutation (SNP) | VAF 50/245 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.472); catalogued as rs1470774275, COSV100359405; called by muse, mutect2, varscan2
- PRTG | c.1538T>C p.L513P | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1396352836, COSV101221236; called by muse, mutect2, varscan2
- PSKH2 | c.1125del p.I376* | Frame Shift Del (DEL) | VAF 37/140 reads (26%) | catalogued as COSV52609211; called by mutect2, pindel, varscan2
- PSMA1 | c.280G>C p.D94H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV101123617; called by muse, mutect2
- PTGES3L-AARSD1 | c.991A>C p.N331H (on ENST00000421990 / NM_001136042.2; = p.N313H on NM_025267.3) | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as COSV100799187; called by muse, mutect2, varscan2
- PTPRN2 | c.2837G>A p.S946N | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.416); catalogued as COSV101153263; called by muse, mutect2, varscan2
- QSER1 | c.4418C>G p.S1473* (on ENST00000399302; = p.S1602* on NM_001076786.3) | Nonsense Mutation (SNP) | VAF 7/41 reads (17%) | catalogued as COSV101234627; called by muse, mutect2, varscan2
- RAD51AP2 | c.2203G>T p.G735C | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV101208281; called by muse, mutect2, varscan2
- RARS2 | c.741G>T p.L247F | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.111); catalogued as COSV101057054, COSV65760912; called by muse, mutect2, varscan2
- RBSN | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.738); catalogued as COSV99514978; called by muse, mutect2, varscan2
- RECQL | c.1529T>C p.L510P | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53712708, COSV99556241; called by muse, mutect2, varscan2
- RHBDF2 | c.2130C>G p.I710M | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV99166172; called by muse, mutect2, varscan2
- RNF216 | c.2582A>G p.Q861R (on ENST00000425013 / NM_207116.3; = p.Q918R on NM_207111.4) | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.889); catalogued as COSV101111257; called by muse, mutect2, varscan2
- RNF40 | c.2007G>A p.M669I | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV100221894; called by muse, mutect2, varscan2
- RPS3 | c.596G>C p.G199A | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV99584252; called by muse, mutect2, varscan2
- RPS6KA6 | c.1982C>T p.S661F | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV53126458; called by muse, mutect2, varscan2
- RPUSD2 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as COSV100225078; called by muse, varscan2
- RRM1 | c.46G>C p.D16H | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as COSV100331211; called by muse, mutect2, varscan2
- RSAD2 | c.845G>C p.R282P | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV101149742, COSV65908404; called by muse, mutect2, varscan2
- SCN1A | c.2633T>C p.M878T (on ENST00000303395 / NM_001202435.3; = p.M867T on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.023); catalogued as COSV100319183; called by muse, mutect2, varscan2
- SECISBP2L | c.2114A>G p.Y705C (on ENST00000559471 / NM_001193489.2; = p.Y660C on NM_014701.4) | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1237503384, COSV99959814; called by muse, mutect2, varscan2
- SGCZ | c.672G>T p.Q224H | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV101166525; called by muse, mutect2
- SGCZ | c.383C>G p.A128G | Missense Mutation (SNP) | VAF 50/261 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as rs770086531, COSV101166526; called by muse, mutect2, varscan2
- SI | c.412C>A p.L138I | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV100013832, COSV52302424; called by muse, mutect2, varscan2
- SIM2 | c.476C>A p.S159* | Nonsense Mutation (SNP) | VAF 16/91 reads (18%) | catalogued as COSV99292843; called by muse, mutect2, varscan2
- SLC17A4 | c.1081C>A p.L361I | Missense Mutation (SNP) | VAF 70/139 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV100930489; called by muse, mutect2, varscan2
- SLC25A12 | c.23C>G p.T8S | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV99784669; called by muse, mutect2, varscan2
- SLC25A14 | c.590G>C p.W197S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99502281; called by muse, mutect2, varscan2
- SLC3A1 | c.1819C>A p.L607I | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as COSV99575907; called by muse, mutect2, varscan2
- SLC5A12 | c.1000C>A p.P334T | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99744367; called by muse, varscan2
- SLC6A18 | c.1672C>A p.R558S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.289); catalogued as COSV99721973, COSV99722482; called by muse, mutect2, varscan2
- SLC8A1 | c.1232T>C p.F411S | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100244359; called by muse, mutect2, varscan2
- SLC9A4 | c.1166C>G p.T389S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99762673; called by muse, mutect2, varscan2
- SLIT2 | c.4543G>A p.E1515K | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as rs768302481, COSV99880616; called by muse, mutect2, varscan2
- SMARCA4 | c.4017G>T p.E1339D | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV100758118; called by muse, mutect2, varscan2
- SMARCA4 | c.4018G>T p.E1340* | Nonsense Mutation (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100758120; called by muse, mutect2, varscan2
- SOD3 | c.323G>T p.S108I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1438300226, COSV101181064; called by muse, mutect2, varscan2
- SORCS1 | c.3040G>A p.G1014R | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV53853752, COSV99543007; called by muse, mutect2, varscan2
- SPATS2L | c.344G>T p.S115I | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.506); catalogued as COSV100660444; called by muse, mutect2, varscan2
- SPIRE2 | c.978+1G>C p.X326_splice | Splice Site (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100988718; called by muse, mutect2, varscan2
- SPTA1 | c.3527G>T p.R1176L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.462); catalogued as COSV100934180, COSV63748414; called by muse, mutect2, varscan2
- STRN | c.1630A>T p.N544Y | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99814916; called by muse, mutect2, varscan2
- TAF4 | c.2945_2946insC p.L982Ffs*89 | Frame Shift Ins (INS) | VAF 13/81 reads (16%) | catalogued as COSV99433405; called by mutect2, pindel, varscan2
- TAPT1 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100460951; called by muse, mutect2
- TCEA3 | c.269G>C p.G90A | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV101004604, COSV65841185, COSV65841326; called by muse, mutect2, varscan2
- TMEM178A | c.654G>T p.G218= | Splice Region (SNP) | VAF 29/177 reads (16%) | catalogued as rs768433672, COSV99931744; called by muse, mutect2, varscan2
- TMEM178A | c.655A>T p.I219L | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV99931745; called by muse, mutect2, varscan2
- TNN | c.2005G>T p.E669* | Nonsense Mutation (SNP) | VAF 18/110 reads (16%) | catalogued as COSV53424371; called by muse, varscan2
- TOM1 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.332); catalogued as rs368486186, COSV101146455; called by muse, mutect2, varscan2
- TOX2 | c.156G>T p.M52I (on ENST00000358131 / NM_001098798.2; = p.M1? on NM_032883.3) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100363310; called by muse, mutect2, varscan2
- TREM2 | c.346A>T p.S116C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as CM140169, COSV100632481; called by muse, mutect2
- TRIM39 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV100935618; called by muse, mutect2, varscan2
- TSHZ3 | c.1283C>T p.T428M | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs375215031, COSV53674983; called by muse, mutect2
- TTF2 | c.1796G>C p.G599A | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101037232; called by muse, mutect2, varscan2
- TTN | c.98764G>T p.V32922L (on ENST00000591111; = p.V25498L on NM_003319.4) | Missense Mutation (SNP) | VAF 18/126 reads (14%) | PolyPhen benign (0.197); catalogued as COSV100593166; called by muse, mutect2, varscan2
- TTN | c.23441T>G p.F7814C (on ENST00000591111; = p.F6887C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | PolyPhen benign (0); catalogued as COSV100593169; called by muse, mutect2, varscan2
- TTYH2 | c.1316G>T p.R439L | Missense Mutation (SNP) | VAF 47/237 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV99482786; called by muse, mutect2, varscan2
- TUBA1C | c.1264C>G p.R422G | Missense Mutation (SNP) | VAF 24/167 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.587); catalogued as rs1254017336; called by muse, mutect2, varscan2
- TUBD1 | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 36/373 reads (10%) | catalogued as COSV100359922, COSV57872021; called by muse, mutect2, varscan2
- TXLNG | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as COSV101200556; called by muse, mutect2, varscan2
- UBR5 | c.1453G>T p.A485S | Missense Mutation (SNP) | VAF 71/138 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as COSV99639230; called by muse, mutect2, varscan2
- USH2A | c.8930C>A p.P2977Q | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.169); catalogued as COSV100228560; called by muse, mutect2, varscan2
- USH2A | c.3491C>A p.S1164Y | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56324736; called by muse, mutect2, varscan2
- USP38 | c.541G>T p.V181L | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV100189058; called by muse, mutect2, varscan2
- USP46 | c.532A>C p.N178H | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101484192; called by muse, mutect2, varscan2
- USP48 | c.2588C>T p.T863I | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV100379436; called by muse, mutect2, varscan2
- VAT1 | c.626G>A p.C209Y | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99887673; called by muse, mutect2, varscan2
- VCPIP1 | c.761A>T p.Q254L | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV100125313; called by muse, mutect2
- VPS35 | c.316C>G p.P106A | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100140439; called by muse, mutect2, varscan2
- ZBTB14 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.264); catalogued as COSV100813411; called by muse, mutect2, varscan2
- ZDHHC18 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 93/251 reads (37%) | SIFT tolerated (0.87); PolyPhen benign (0.01); catalogued as rs1264434432, COSV100938803; called by muse, mutect2, varscan2
- ZFHX4 | c.9204G>T p.K3068N | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1330160261, COSV51488511; called by muse, mutect2, varscan2
- ZFP57 | c.325C>T p.H109Y | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100971802; called by muse, mutect2, varscan2
- ZNF12 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 64/193 reads (33%) | catalogued as COSV100703556; called by muse, mutect2, varscan2
- ZNF12 | c.66G>T p.W22C | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100703557, COSV61243830; called by muse, mutect2, varscan2
- ZNF385D | c.446C>G p.T149S | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0.039); catalogued as COSV55751815, COSV99873201; called by muse, mutect2, varscan2
- ZNF827 | c.1104G>C p.E368D | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101061133; called by muse, mutect2, varscan2
- ZNF862 | c.2933G>T p.C978F | Missense Mutation (SNP) | VAF 94/163 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV99783171; called by muse, mutect2, varscan2
- ZP1 | c.959C>T p.T320M | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs76136580, COSV99612151; called by muse, mutect2, varscan2
- ZRANB2 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as COSV99638898; called by mutect2, varscan2
- ATM | c.2456del p.C819Lfs*4 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | called by mutect2, pindel, varscan2
- CLDN12 | c.659dup p.Y220* | Nonsense Mutation (INS) | VAF 110/342 reads (32%) | called by mutect2, pindel, varscan2
- CRYBG2 | c.1328G>T p.R443M | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CRYBG2 | c.605C>A p.S202Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- FSCB | c.1668del p.A557Lfs*13 | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | called by mutect2, pindel, varscan2
- IGKV1D-16 | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.7); called by muse, varscan2
- IGLC3 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 9/61 reads (15%) | PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- LPO | c.1656del p.I553Sfs*29 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | called by mutect2, pindel, varscan2
- MRC1 | c.1622C>T p.T541I | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- OLAH | c.788C>A p.S263Y (on ENST00000378228 / NM_001039702.3; = p.S316Y on NM_018324.3) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2
- OR8G2P | c.808del p.Q270Rfs*16 | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | called by mutect2, varscan2
- PFKM | c.212del p.E71Gfs*5 | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | called by mutect2, varscan2
- RET | c.3142dup p.L1048Pfs*11 | Frame Shift Ins (INS) | VAF 18/90 reads (20%) | called by mutect2, pindel, varscan2
- RFXANK | c.700G>T p.G234* | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- SCN7A | c.3245del p.G1082Afs*21 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by pindel, varscan2
- SPTA1 | c.4587dup p.D1530Rfs*4 | Frame Shift Ins (INS) | VAF 42/175 reads (24%) | called by mutect2, pindel, varscan2
- TAF3 | c.1693del p.D565Tfs*38 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- TRBV24-1 | c.190T>A p.L64M | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRRAP | c.11483del p.F3828Sfs*8 (on ENST00000359863 / NM_001244580.1; = p.F3799Sfs*8 on NM_003496.3) | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel, varscan2
- ABCA4 | c.2145G>T p.L715= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV100933018; called by muse, mutect2, varscan2
- ACTL6B | c.1149C>T p.T383= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV99355413; called by muse, mutect2, varscan2
- AHNAK2 | c.2697G>T p.V899= | Silent (SNP) | VAF 110/332 reads (33%) | catalogued as COSV100315408; called by muse, mutect2, varscan2
- AP002512.3 | c.990C>T p.R330= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV54405516; called by muse, mutect2, varscan2
- AQP12A | c.90A>G p.P30= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV100538609; called by muse, mutect2, varscan2
- BCL11A | c.525G>T p.P175= (on ENST00000335712 / NM_001365609.1; = p.P209= on NM_018014.4) | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100184711; called by muse, mutect2, varscan2
- BCR | c.3213G>T p.V1071= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100005925; called by muse, mutect2, varscan2
- CPS1 | c.579G>T p.V193= | Silent (SNP) | VAF 19/133 reads (14%) | catalogued as COSV99242081; called by muse, mutect2, varscan2
- CPSF3 | c.333C>A p.V111= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV53008949; called by muse, mutect2, varscan2
- CRYBG3 | c.8217C>G p.V2739= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as rs1381601985, COSV51710151, COSV99476580; called by muse, mutect2, varscan2
- CSF3R | c.2445A>T p.P815= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100117301, COSV58969983; called by muse, mutect2, varscan2
- DIDO1 | c.4167G>A p.E1389= | Silent (SNP) | VAF 15/146 reads (10%) | catalogued as COSV56623954, COSV99824618; called by muse, mutect2, varscan2
- EMSY | c.3423T>C p.S1141= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as COSV100595357; called by muse, mutect2, varscan2
- EPHA3 | c.2241C>A p.L747= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV60702326, COSV60707950; called by muse, mutect2
- FARP2 | c.1255C>T p.L419= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV99883818; called by muse, mutect2, varscan2
- FBXO43 | c.825T>C p.D275= | Silent (SNP) | VAF 48/69 reads (70%) | catalogued as COSV101413785; called by muse, mutect2, varscan2
- GALNT1 | c.579A>G p.R193= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs776101137, COSV99321837; called by muse, mutect2, varscan2
- HSF5 | c.282G>T p.L94= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100050737; called by muse, mutect2, varscan2
- IFT122 | c.3306C>T p.I1102= (on ENST00000348417 / NM_052989.3; = p.I1043= on NM_018262.4) | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV99958680; called by muse, mutect2, varscan2
- KRTAP4-5 | c.432C>T p.C144= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100576753; called by muse, mutect2, varscan2
- KTI12 | c.366G>A p.A122= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as rs143842489; called by muse, mutect2, varscan2
- LAMA4 | c.4260C>A p.S1420= (on ENST00000230538 / NM_001105206.3; = p.S1413= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV100037521; called by muse, mutect2, varscan2
- LARGE1 | c.390G>T p.P130= | Silent (SNP) | VAF 42/137 reads (31%) | catalogued as COSV100504504; called by muse, mutect2, varscan2
- LRRTM4 | c.1035C>T p.I345= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV101297416, COSV101297515; called by muse, mutect2
- MACF1 | c.3972A>G p.A1324= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs768930030, COSV100482299; called by muse, mutect2, varscan2
- MAOB | c.1488T>A p.I496= | Silent (SNP) | VAF 50/59 reads (85%) | catalogued as COSV100955890; called by muse, mutect2, varscan2
- MAP2K5 | c.468A>T p.L156= | Silent (SNP) | VAF 32/62 reads (52%) | catalogued as COSV99459341; called by muse, mutect2, varscan2
- MRPS34 | c.522T>A p.I174= | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as rs1250743973, COSV99167646; called by muse, mutect2, varscan2
- MYO9B | c.3402G>T p.A1134= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV101261231; called by muse, mutect2, varscan2
- NCAM2 | c.2202C>T p.C734= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs1171396044, COSV99520968; called by muse, mutect2, varscan2
- NELL1 | c.240G>T p.L80= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs1483190339, COSV100118729; called by muse, mutect2, varscan2
- NXF3 | c.1417C>A p.R473= | Silent (SNP) | VAF 32/93 reads (34%) | catalogued as COSV67703318; called by muse, mutect2, varscan2
- OCA2 | c.99C>A p.A33= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100666916; called by muse, mutect2, varscan2
- OR2M2 | c.786C>T p.P262= | Silent (SNP) | VAF 65/344 reads (19%) | catalogued as COSV62898634; called by muse, mutect2, varscan2
- OR4M1 | c.666G>T p.L222= | Silent (SNP) | VAF 76/318 reads (24%) | catalogued as rs1440437818, COSV60062063; called by muse, mutect2, varscan2
- PCDHA1 | c.628T>C p.L210= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV100974254; called by muse, mutect2, varscan2
- PCDHA8 | c.1887C>A p.G629= | Silent (SNP) | VAF 33/140 reads (24%) | catalogued as COSV100968976; called by muse, mutect2, varscan2
- PCLAF | c.21C>T p.D7= | Silent (SNP) | VAF 33/205 reads (16%) | catalogued as COSV100256815; called by muse, mutect2, varscan2
- PIK3R2 | c.1636C>T p.L546= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV99717172; called by muse, mutect2, varscan2
- PLBD1 | c.159A>G p.T53= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as rs1225775103, COSV99554217; called by muse, mutect2, varscan2
- PPIL2 | c.795C>T p.A265= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as COSV100622421; called by muse, mutect2, varscan2
- PPP3CB | c.816A>T p.P272= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100646028; called by muse, mutect2
- REPS2 | c.1383T>C p.S461= | Silent (SNP) | VAF 41/150 reads (27%) | catalogued as COSV100380787; called by muse, mutect2, varscan2
- SLC17A4 | c.1080C>A p.I360= | Silent (SNP) | VAF 69/138 reads (50%) | catalogued as COSV100930488, COSV64957283; called by muse, mutect2, varscan2
- SLC7A9 | c.498C>T p.N166= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99195184; called by muse, mutect2, varscan2
- SLCO5A1 | c.420C>A p.I140= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as rs1483255058, COSV52666837, COSV99479342, COSV99481399; called by muse, mutect2, varscan2
- STAC2 | c.1110C>T p.Y370= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as rs747691222, COSV100336269; called by muse, mutect2, varscan2
- STBD1 | c.12C>G p.V4= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as COSV99421374, COSV99421558; called by muse, mutect2, varscan2
- SYNPO | c.1455G>A p.R485= (on ENST00000394243 / NM_001166208.2; = p.R241= on NM_007286.6) | Silent (SNP) | VAF 9/104 reads (9%) | catalogued as rs761447727, COSV100301841; called by muse, mutect2
- TANC2 | c.399T>A p.T133= | Silent (SNP) | VAF 30/423 reads (7%) | catalogued as COSV101267188; called by muse, mutect2
- TCHH | c.261T>C p.Y87= | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as COSV100914891; called by muse, mutect2, varscan2
- TIE1 | c.3204G>A p.Q1068= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs1011487024, COSV100991975; called by muse, mutect2, varscan2
- TIRAP | c.234C>T p.G78= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV101201546; called by muse, mutect2, varscan2
- TLR7 | c.834C>T p.P278= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as COSV66123992; called by muse, mutect2, varscan2
- TMEM144 | c.186A>G p.P62= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV99646614; called by muse, mutect2, varscan2
- UHRF1 | c.105G>C p.L35= (on ENST00000612630 / NM_001290050.1; = p.L48= on NM_013282.4) | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV99503280; called by muse, mutect2, varscan2
- USP38 | c.786A>G p.V262= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV100189060; called by muse, mutect2, varscan2
- USP48 | c.2589C>T p.T863= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as COSV100379434; called by muse, mutect2, varscan2
- XRN2 | c.2796C>T p.P932= | Silent (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2
- ZAN | c.8064C>G p.P2688= | Silent (SNP) | VAF 24/128 reads (19%) | catalogued as COSV100769093; called by muse, mutect2, varscan2
- ZC3H11A | c.864A>G p.K288= | Silent (SNP) | VAF 9/156 reads (6%) | catalogued as COSV100142127; called by muse, mutect2
- ZNF586 | c.738C>T p.N246= | Silent (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2
- ZPLD1 | c.813G>T p.R271= (on ENST00000466937 / NM_001329788.1; = p.R287= on NM_175056.2) | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV100082877; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501882 ins A | 5'Flank (INS) | VAF 4/26 reads (15%) | catalogued as rs770119759; called by mutect2, pindel
- CIT | c.2082+1922C>G | Intron (SNP) | VAF 51/116 reads (44%) | catalogued as COSV99948302; called by muse, mutect2, varscan2
- CNEP1R1 | c.25+350G>A | Intron (SNP) | VAF 7/37 reads (19%) | catalogued as COSV101208030; called by muse, mutect2, varscan2
- GABRG2 | c.1249-1357C>T | Intron (SNP) | VAF 12/90 reads (13%) | catalogued as rs747426141, COSV62718552; called by muse, mutect2, varscan2
- HERC2P3 | n.815G>A | RNA (SNP) | VAF 46/318 reads (14%) | called by muse, varscan2
- HERC2P3 | n.814G>A | RNA (SNP) | VAF 45/312 reads (14%) | called by muse, varscan2
- PKD1L2 | n.2693C>A | RNA (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- SNORD115-13 | n.78G>T | RNA (SNP) | VAF 44/455 reads (10%) | called by muse, mutect2, varscan2
- SPAG11B | chr8:7448033 G>A | 3'Flank (SNP) | VAF 13/36 reads (36%) | catalogued as rs758325558, COSV99872703; called by muse, mutect2, varscan2
